TCGA case TCGA-BL-A0C8 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Christiana Healthcare. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a6003b1c-56a9-430a-a5e2-b70af3f81bdb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Year of birth: 1936; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.1; Tissue or organ of origin: Dome of bladder; Site of resection or biopsy: Dome of bladder; Age at diagnosis: 73.4 years (26,819 days); Year of diagnosis: 2009; Days to diagnosis: 0 days; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,219 days (3.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Exposures
- Pack years smoked: 10; Cigarettes per day: 0.547945205479452.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BL-A0C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 790 mg.
  Slide TCGA-BL-A0C8-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 32; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
  Slide TCGA-BL-A0C8-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 45; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 22.
- Sample TCGA-BL-A0C8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide TCGA-BL-A0C8-01B-03-BS3: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BL-A0C8-01B-04-BS4: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BL-A0C8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BL-A0C8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Height cm at diagnosis: 178 cm; Weight kg at diagnosis: 134.4 kg; History neoadjuvant treatment: No; Occupation current: retired; Occupation primary: fork lift operator; Occupation primary industry: Automotive assembly industry; Tobacco smoking history indicator: 3; Tobacco smoking age started: 13; Tobacco smoking year stopped: 1959; Histologic subtype: Non-Papillary; Tumor grade: High Grade; Anatomic organ subdivision: Dome; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined count: 0; Lymph nodes examined he count: 0; Incidental prostate cancer indicator: No.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event type: No New Tumor Event.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event 1: Days from index date to new tumor event diagnosis: 630; New tumor event type: Locoregional (Urothelial tumor event); New tumor event surgery: Yes; Days from index date to new tumor event surgery: 630; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2, New tumor event 2: Days from index date to new tumor event diagnosis: 791; New tumor event type: Locoregional (Urothelial tumor event); New tumor event surgery: Yes; Days from index date to new tumor event surgery: 791; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 680; Days from index date to pharmaceutical treatment ended: 722; Pharmaceutical therapy drug name: BCG; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Immunotherapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Item does not meet study protocol: This is a non-muscle invasive pT1 bladder cancer submitted before the pT2 requirement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,219 days; disease-specific survival: no event (censored), 1,219 days; disease-free interval: event (new tumor event after initially disease-free), 630 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 630 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BL-A0C8-01A-11D-A273-01): tumor purity 0.59, ploidy 3.54, whole-genome doublings 1.
